Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5724, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5724-01A (Primary Tumor).

*** Diagnosis(es): ***

Total gastrectomy specimen with an ulcerated gastric carcinoma of the antrum of maximum diameter 5 cm extending to a maximum of 2 cm from the aboral resection margin, localized on the lesser curvature side and invading the anterior and posterior wall, of the histological type of a poorly differentiated adenocarcinoma (diffuse type of gastric carcinoma). Invasive tumor dissemination within all gastric wall layers into the perigastric fatty tissue, subserosa and penetration of the serosa. Antral mucosa with non-florid, moderate chronic gastritis, foveolar hyperplasia and focal intestinal metaplasia; corpus mucosa with slight, non-florid chronic gastritis of the superficial type.

Thirty-four of forty perigastric lymph nodes with extensive metastases from the gastric carcinoma. Greater omentum with multiple coarsely nodular metastases from the gastric carcinoma.

Oral and aboral resection margin and isolated occurrence of esophageal and duodenal cuff tumor-free.

Therefore tumor stage: pT3, pN3 (34/40) [REDACTED].

Source: NCI Genomic Data Commons file 395f08e9-119f-4211-8637-04510b175f8c (TCGA-CG-5724.2310EECA-651B-4CF6-940B-0A4F8C7D171B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).